Surgical pathology report (de-identified scan), TCGA case TCGA-64-1676, project TCGA-LUAD (Lung Adenocarcinoma), tissue source site Fox Chase, specimen TCGA-64-1676-01A (Primary Tumor).

[page 1 of 5]
Clinical History/Diagnosis: Right Lung CA

Source of Specimen(s):

- 1: bx @ 42 cm
- 2: bx @ 40 cm
- 3: bx @ 34 cm
- 4: Portion of right 6th rib
- 5: Lymph Node, level 9
- 6: Lymph Node, level 11
- 7: Rt, lower lobe
- 8: Lymph Node, level 8
- 9: Lymph Node, level 10
- 10: Lymph Node, 4R
- 11: Lymph Node, level 7

Gross Description:

Received in eleven parts.

Source of Tissue: 1. Labeled #1, "biopsy at 42 cm"

Gross Description: Received fresh with patient name and medical record number labeled "biopsy at 42 cm" is a 0.3 cm light-tan irregular soft tissue fragment which is submitted in toto in one block.

Designation of Sections: Block 1

Summary of Sections: undesignated-1

Source of Tissue: 2. Labeled #2, "biopsy at 40 cm"

Gross Description: Received fresh with patient name and medical record number labeled "biopsy at 40 cm" are two light-tan irregular soft tissue fragments, 0.2 cm in greatest dimension. They are submitted in total in one block.

Designation of Sections: Block 2

Summary of Sections: undesignated-2

Source of Tissue: 3. Labeled #3, "biopsy at 34 cm"

Gross Description: Received fresh with patient name and medical record

[page 2 of 5]
number labeled "biopsy at 34 cm" is a 0.4 cm light-tan irregular soft tissue fragment which is submitted in toto in one block.

Designation of Sections: Block 3

Summary of Sections: undesignated-1

Source of Tissue: 4. Labeled #4, "portion of right 6th rib"

Gross Description: Received fresh with patient name and medical record number labeled "portion of right 6th rib" is a 2.0 cm in length tan fragment of rib having a moderate amount of attached soft tissue and muscle. A representative section is submitted in one block, following decalcification.

Designation of Sections: Block 4

Summary of Sections: undesignated-1

Source of Tissue: 5. Labeled #5, "level 9 lymph node"

Gross Description: Received fresh with patient name and medical record number labeled "level 9 lymph node" is a 1.0 cm in greatest dimension gray-black anthracotic stained lymph node which is submitted in toto in one block.

Designation of Sections: Block 5

Summary of Sections: undesignated-1

Source of Tissue: 6. Labeled #6, "level 11 lymph node"

Gross Description: Received fresh with patient name and medical record number labeled "level 11 lymph node" are 1.5 x 1.0 x 0.4 cm of gray-black anthracotic stained tissue fragments which are entirely submitted in one block.

Designation of Sections: Block 6

Summary of Sections: undesignated-multiple

Source of Tissue: 7. Labeled #7, "right lower lobe"

[page 3 of 5]
Frozen Section Diagnosis: 7FS- BRONCHIAL MARGIN WITH NO TUMOR.

Gross Description: Received fresh for frozen section evaluation with patient name and medical record number labeled "right lower lobe" is a 296 gram, 18.0 x 12.5 x 4.5 cm right lower lobectomy of lung. It is covered by a tan-pink to red-purple focally anthracotic stained pleura having up to 0.5 cm of attached bronchus. The bronchial resection margin is submitted for frozen section evaluation and the frozen section residue is submitted in one block. Adjacent to the bronchus, in the superior aspect of the specimen there is a 2.5 x 2.0 x 2.0 cm firm mass having tan cut surfaces with irregular borders. The remaining cut surfaces of lung range from areas which are tan-pink and crepitant to areas which are red-purple, soft and glistening. There are few palpable peribronchial lymph nodes, 0.8 cm in greatest dimension. The cut surface of each is gray-black and anthracotic stained. Representative sections are submitted in eight blocks.

Designation of Sections: 7FS- frozen section bronchial resection margin, 7A- vascular margins, 7B-7F- mass, 7G- random lung sections, 7H- peribronchial lymph nodes

Summary of Sections: multiple

Source of Tissue: 8. Labeled #8, "level 8 lymph node"

Gross Description: Received fresh with patient name and medical record number labeled "level 8 lymph node" is a 0.8 cm tan-pink fragment of soft tissue which is submitted in toto in one block.

Designation of Sections: Block 8

Summary of Sections: undesignated-1

Source of Tissue: 9. Labeled #9, "level 10 lymph node"

Gross Description: Received fresh with patient name and medical record number labeled "level 10 lymph node" are two gray-black anthracotic stained tissue fragments, 0.8 cm in greatest dimension. They are submitted in toto in one block.

Designation of Sections: Block 9

Summary of Sections: undesignated-2

[page 4 of 5]
Source of Tissue: 10. Labeled #10, "4R lymph node"

Gross Description: Received fresh with patient name and medical record number labeled "4R lymph node" are 2.0 x 1.0 x 0.5 cm of yellow-tan focally anthracotic stained fragments of fibroadipose tissue. They are entirely submitted in one block.

Designation of Sections: Block 10

Summary of Sections: undesignated-multiple

Source of Tissue: 11. Labeled #11, "level 7 lymph node"

Gross Description: Received fresh with patient name and medical record number labeled "level 7 lymph node" are two gray-black anthracotic stained tissue fragments, 1.5 cm in greatest dimension. They are entirely submitted in two blocks.

Designation of Sections: 11A-11B

Summary of Sections: multiple

Final Diagnosis:

1) 42 cm, site unspecified (biopsy):

-Fragments of squamous mucosa with no specific pathologic abnormality.

-No tumor seen.

2) 40 cm, site unspecified (biopsy):

-Fragments of squamous mucosa with no specific pathologic abnormality.

-No tumor seen.

3) 34 cm, site unspecified (biopsy):

-Fragments of squamous mucosa with no specific pathologic abnormality.

-No tumor seen.

4) Right sixth rib (excision):

-Unremarkable rib and marrow.

-No tumor seen.

5) Lymph node, level 9 (excision):

-One lymph node negative for metastatic carcinoma (0/1).

6) Lymph nodes, level 11 (excision):

-Ten lymph nodes negative for metastatic carcinoma (0/10).

[page 5 of 5]
7) Lung, right lower lobe (lobectomy):

- Poorly differentiated non-small cell carcinoma (2.5 cm gross measurement).
- The centrally located tumor has a predominately solid architectural pattern and abundant areas of necrosis.
- No angiolymphatic space invasion is identified.
- The visceral pleura is negative for tumor.
- The bronchial and vascular margins are negative for tumor.
- Five peribronchial and one intrapulmonary lymph node are negative for metastatic carcinoma (0/6).

8) Lymph node, level 8 (excision):

- One lymph node negative for metastatic carcinoma (0/1).

9) Lymph nodes, level 10 (excision):

- Two lymph nodes negative for metastatic carcinoma (0/2).

10) Lymph nodes, level 4R (excision):

- Six lymph nodes negative for metastatic carcinoma (0/6).

11) Lymph nodes, level 7 (excision):

- Four lymph nodes negative for metastatic carcinoma (0/4).

-pT1 NO MX

Source: NCI Genomic Data Commons file 5ccc8d03-d4e2-4a17-b3e0-0664c22e9b2c (TCGA-64-1676.516B08AF-72B5-4B4A-B208-3C874ABE63AD.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).